Somatic mutation profile of tumor specimen MP2PRT-PASSAV-TMP1-B (aliquot MP2PRT-PASSAV-TMP1-B-1-0-D-A83C-36) from MP2PRT case MP2PRT-PASSAV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,194 days).
Specimen MP2PRT-PASSAV-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec4bd2a0-8373-4edf-8d0e-d4f117c8d1b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASSAV-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASSAV-NM1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb1fb558-2cb8-4387-838b-9c977f6df428

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Nonsense Mutation 5, 5'UTR 2, Splice Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 120/473 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, mutect2, varscan2
- ACER1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 128/347 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs144461069, COSV100034169; called by muse, mutect2, varscan2
- COL6A3 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 190/437 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369379463, COSV55093992; called by muse, mutect2, varscan2
- KCND2 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 155/407 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58576645; called by muse, mutect2, varscan2
- KHDC1 | c.539G>A p.R180Q (on ENST00000370384 / NM_001251874.2; = p.R107Q on NM_030568.5) | Missense Mutation (SNP) | VAF 118/289 reads (41%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.947); catalogued as rs1418927716; called by muse, mutect2, varscan2
- KIF5A | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 11/311 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1457616326, COSV99673482; called by muse, mutect2
- MYO10 | c.1705C>T p.R569* | Nonsense Mutation (SNP) | VAF 80/245 reads (33%) | catalogued as COSV101569784; called by muse, mutect2, varscan2
- MYOM2 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 194/459 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1403533352, COSV50798487; called by muse, mutect2, varscan2
- PLCL1 | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 54/188 reads (29%) | catalogued as rs752979149, COSV101407168; called by muse, mutect2, varscan2
- PNPLA7 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs753570344, COSV52998605; called by muse, mutect2, varscan2
- RIN1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 305/726 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1252084781; called by muse, mutect2, varscan2
- SLC4A7 | c.1334C>G p.A445G | Missense Mutation (SNP) | VAF 182/424 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55394674; called by muse, mutect2
- TGFBRAP1 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 219/561 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as rs140106209; called by muse, mutect2, varscan2
- TTN | c.17638+1G>A p.X5880_splice (on ENST00000591111; = p.X4953_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 92/273 reads (34%) | catalogued as COSV59919571; called by muse, mutect2, varscan2
- ZNF2 | c.511C>T p.R171* (on ENST00000611147 / NM_001291605.2; = p.R158* on NM_021088.4) | Nonsense Mutation (SNP) | VAF 135/392 reads (34%) | catalogued as COSV54637683; called by muse, mutect2, varscan2
- AP5B1 | c.2248C>A p.L750I | Missense Mutation (SNP) | VAF 23/727 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); called by muse, mutect2
- FRAS1 | c.663C>A p.C221* | Nonsense Mutation (SNP) | VAF 24/426 reads (6%) | called by muse, mutect2
- OMD | c.677C>G p.S226* | Nonsense Mutation (SNP) | VAF 90/253 reads (36%) | called by muse, mutect2, varscan2
- OTOG | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMARCA5 | c.1909C>T p.L637F | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SOX3 | c.991T>G p.S331A | Missense Mutation (SNP) | VAF 144/444 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.155); called by mutect2, varscan2
- C2orf16 | c.801G>A p.P267= | Silent (SNP) | VAF 109/251 reads (43%) | catalogued as rs747398801; called by muse, mutect2, varscan2
- FLNA | c.3144C>T p.D1048= | Silent (SNP) | VAF 268/682 reads (39%) | catalogued as rs782759078; called by muse, mutect2, varscan2
- HMGB2 | c.429A>G p.P143= | Silent (SNP) | VAF 120/307 reads (39%) | catalogued as rs775510835; called by muse, mutect2, varscan2
- IL36A | c.210C>G p.L70= | Silent (SNP) | VAF 134/346 reads (39%) | called by muse, mutect2, varscan2
- PHACTR1 | c.210G>A p.P70= | Silent (SNP) | VAF 13/415 reads (3%) | called by muse, mutect2
- PIWIL1 | c.2493T>G p.P831= | Silent (SNP) | VAF 106/265 reads (40%) | called by muse, mutect2, varscan2
- ZNF512B | c.1602G>A p.Q534= | Silent (SNP) | VAF 187/476 reads (39%) | called by muse, mutect2
- AGTPBP1 | c.-95C>G | 5'UTR (SNP) | VAF 205/670 reads (31%) | called by muse, mutect2, varscan2
- GRK2 | c.*979dup | 3'UTR (INS) | VAF 146/432 reads (34%) | catalogued as rs781487718; called by mutect2, varscan2
- MYL3 | chr3:46830457 C>G | 3'Flank (SNP) | VAF 121/302 reads (40%) | catalogued as rs1321492843; called by muse, mutect2, varscan2
- RAN | c.-1G>C | 5'UTR (SNP) | VAF 151/411 reads (37%) | called by muse, mutect2, varscan2
